Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9F0, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9F0-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Melanoma, epithelioid &
spindle cell mixed 8720/3
Site: Uveal tract C69.4
2/16/14

Enucleation of the left eye.

Macroscopy:

The eyeball measures 25 mm in diameter and the posterior optic nerve segment 7 mm. Tissue specimens have been taken for cryopreservation and then the piece has been fixed and included entirely.

Microscopy

*See path discrepancy form for
epithelioid and spindle cell ratio.*

The eyeball presents a tumor exhibiting the morphology of an uveal melanoma composed of fusiform (40%) and of epithelioid cells (60%). Important melanotic pigmentation. The mitotic index is very low. There is no necrosis.

The tumor invades the ciliary body. The sclera, the optic nerve on its entire course, the meningeal sheath and the end cut of the optic nerve are free of tumor. There is no extrascleral extension.

The tumor size is 12X7 mm main lines

Conclusion:

Uveal melanoma composed of fusiform and of epithelioid cells.

Tumor size: 12X7 mm.

Low mitotic index.

Tumor extension of the ciliary body

No extrascleral extension.

Sclera, optic nerve in its entire course, cut end of the optic nerve and meningeal sheaths free of tumor.

Tumor Malignancy History		/

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	60% epithelioid cells 40% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% epithelioid cells 1-30% spindle cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 5c974844-d3f0-4ee5-b1fe-486419e9731f (TCGA-V4-A9F0.4705E851-FE91-4FCF-94FC-4872A381DED4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).